HCMI case HCM-BROD-0703-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/45ae5a7e-95c8-453c-bd9d-446cd0f3734e

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Year of birth: 1965; Vital status: Dead; Days to death: 481 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 53.3 years (19,452 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: TX; AJCC pathologic N: N3b; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Sites of involvement: Distant Nodes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFOX; Days to treatment start: 11 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 11 days; Days to treatment end: 306 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Neoadjuvant; Days to treatment start: 11 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Ramucirumab; Treatment intent type: Neoadjuvant; Days to treatment start: 307 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Ramucirumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 307 days; Days to treatment end: 363 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erdafitinib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 381 days (1.0 years); Days to treatment end: 477 days (1.3 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 381 days (1.0 years); Days to treatment end: 477 days (1.3 years).
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; neoadjuvant Radiation Therapy, NOS; Surgery, NOS, for initial diagnosis.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 54.3 years (19,833 days); Days to diagnosis: 381 days (1.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Paclitaxel; Treatment intent type: Maintenance Therapy; Days to treatment start: 307 days; Days to treatment end: 363 days; Treatment outcome: Progressive Disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 481 days (1.3 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 478.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: GERD.
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 144 cm; BMI: 28.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Gastric Cancer.

Biospecimens (3 samples)
- Sample HCM-BROD-0703-C16-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Samples HCM-BROD-0703-C16-85M, HCM-BROD-0703-C16-85N (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
